Somatic mutation profile of tumor specimen TCGA-R3-A69X-01A (aliquot TCGA-R3-A69X-01A-22D-A30E-08) from TCGA case TCGA-R3-A69X, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.0 years (25,576 days).
Specimen TCGA-R3-A69X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b468536-c710-4af5-9d9e-88c43279eb0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R3-A69X-10A (Blood Derived Normal), aliquot TCGA-R3-A69X-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/613d08ba-b2a6-43d3-b1d8-39fcd37b3ae2

The open-access MAF lists 228 somatic variants for this specimen: 171 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 52, Nonsense Mutation 15, Splice Site 3, RNA 2, Frame Shift Del 2, 5'Flank 1, Splice Region 1, 3'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC12A3 | c.3026G>A p.R1009Q (on ENST00000563236 / NM_001126108.2; = p.R1018Q on NM_000339.3) | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs370175770, CM078122, CM130829; ClinVar: pathogenic; called by muse, varscan2
- AASDH | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV52709785, COSV99222090; called by muse, mutect2
- ABHD10 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as COSV56326056; called by muse, mutect2, varscan2
- ACAP3 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs745323169, COSV57644079; called by muse, varscan2
- ADAMTS18 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 67/388 reads (17%) | catalogued as COSV51414083, COSV99272584; called by muse, mutect2, varscan2
- ADGRE3 | c.1590G>C p.L530F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568478857, COSV53733412; called by muse, mutect2
- ANGPTL3 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV52018907; called by muse, mutect2, varscan2
- ANO3 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99882809; called by muse, mutect2
- ARHGAP4 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs782099184, COSV63133967; called by muse, mutect2, varscan2
- ARNT2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 36/401 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57589721, COSV57590066; called by muse, mutect2
- ATM | c.9157A>T p.K3053* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs1555152104, COSV99589604; ClinVar: uncertain significance; called by muse, varscan2
- ATP13A5 | c.1994T>A p.L665* | Nonsense Mutation (SNP) | VAF 12/188 reads (6%) | catalogued as COSV100665140; called by muse, mutect2
- ATP23 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55687100; called by muse, mutect2, varscan2
- ATP6V1H | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99050955; called by muse, mutect2
- ATP8A1 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs1256435467, COSV52546029; called by muse, mutect2, varscan2
- ATR | c.6403C>T p.P2135S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs1472375950, COSV63391021; called by muse, mutect2, varscan2
- AXDND1 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV62647277; called by muse, mutect2, varscan2
- C2CD3 | c.3620G>C p.C1207S | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV58099329; called by muse, mutect2, varscan2
- C5orf22 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57599810; called by muse, varscan2
- CARMIL3 | c.2401G>C p.E801Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV57728057; called by muse, mutect2, varscan2
- CDH10 | c.2269G>C p.E757Q | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV52594272; called by muse, mutect2, varscan2
- CHD7 | c.3712G>A p.V1238I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.364); catalogued as rs794727150, COSV71106845, COSV71112911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHFR | c.745G>A p.D249N (on ENST00000432561 / NM_001161345.1; = p.D208N on NM_018223.2) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV57177419; called by muse, mutect2, varscan2
- CLUL1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs906123764, COSV58113224; called by muse, mutect2, varscan2
- CNNM3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1331333525, COSV59709830; called by muse, mutect2, varscan2
- CPS1 | c.712-1G>A p.X238_splice | Splice Site (SNP) | VAF 20/178 reads (11%) | catalogued as COSV51822026; called by mutect2, varscan2
- CRYBA2 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55388615; called by muse, mutect2, varscan2
- CUBN | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100912666, COSV64726404; called by muse, mutect2
- CYRIA | c.501C>G p.I167M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV62866808; called by muse, mutect2
- DAG1 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV58186704; called by muse, mutect2, varscan2
- DEPDC1 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV63959121; called by muse, mutect2, varscan2
- DLK2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV99766837, COSV99767259; called by muse, mutect2
- DNAH3 | c.10402C>G p.Q3468E | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV54545885; called by muse, mutect2, varscan2
- DNAJC10 | c.2080G>C p.D694H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51144800; called by muse, mutect2, varscan2
- DSCAM | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs780886519, COSV68025073; called by muse, mutect2, varscan2
- EIF3A | c.769C>G p.H257D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100974495, COSV64962965; called by muse, mutect2, varscan2
- EIF3A | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100974609; called by muse, mutect2, varscan2
- ELF3 | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62837952; called by muse, mutect2, varscan2
- ENAM | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV68536819; called by muse, mutect2, varscan2
- ENOPH1 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV56732021; called by muse, mutect2, varscan2
- ETNPPL | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV56597245; called by muse, mutect2, varscan2
- FASTK | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs762714514, COSV52542045; called by muse, mutect2, varscan2
- FCGR2B | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99375073; called by muse, mutect2, varscan2
- FGD6 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.198); catalogued as COSV59696487; called by muse, mutect2, varscan2
- FMN2 | c.4198C>T p.Q1400* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV60452224; called by muse, mutect2, varscan2
- GABRE | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV64821000; called by muse, mutect2, varscan2
- GDA | c.1358C>A p.S453* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52997643, COSV99429231; called by muse, mutect2, varscan2
- GRID2 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | catalogued as COSV99940828; called by muse, mutect2, varscan2
- GRIN2B | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV74207442; called by muse, mutect2
- GRK4 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100054624, COSV58627410; called by muse, mutect2, varscan2
- GRM2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV56587049; called by muse, mutect2, varscan2
- GTF3C4 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs141734420; called by muse, mutect2, varscan2
- GYPA | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.085); catalogued as COSV99301842; called by muse, mutect2
- HCN2 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210398175, COSV52118170; called by muse, mutect2, varscan2
- HELLS | c.2023C>T p.R675* | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | catalogued as COSV53295804, COSV99491988; called by muse, mutect2, varscan2
- HHIP | c.1572T>A p.S524R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV56843370; called by muse, mutect2, varscan2
- HS2ST1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59356926; called by muse, mutect2, varscan2
- HYDIN | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55493140, COSV55496589; called by muse, mutect2, varscan2
- IFT81 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV99655982; called by muse, mutect2
- INSIG1 | c.671T>C p.I224T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV60921101; called by muse, mutect2, varscan2
- JCAD | c.3568G>C p.E1190Q | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs758055788, COSV64761355; called by muse, mutect2, varscan2
- KIF17 | c.2955C>A p.N985K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV99929031; called by muse, mutect2, varscan2
- KIF26B | c.2691G>T p.Q897H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV63649907; called by muse, mutect2, varscan2
- KLHL4 | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100909706, COSV64143196, COSV64146937; called by muse, mutect2, varscan2
- KLRG2 | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV61801491; called by muse, varscan2
- KRIT1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV60670123; called by muse, mutect2, varscan2
- KRTAP9-9 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 71/320 reads (22%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.631); catalogued as COSV67454076, COSV67454181; called by muse, varscan2
- LDLR | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV52945537; called by muse, mutect2, varscan2
- LHX9 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV61326779; called by muse, mutect2
- LILRA4 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs778509745, COSV52494298; called by muse, mutect2, varscan2
- LPAR1 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62691112; called by muse, mutect2, varscan2
- LRRC36 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV52081718; called by muse, mutect2, varscan2
- LYST | c.6368G>A p.G2123E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as COSV67710117; called by muse, mutect2
- LZTR1 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV53148429; called by muse, mutect2, varscan2
- MAB21L1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.086); catalogued as rs1410180245, COSV59815940; called by muse, mutect2, varscan2
- MAP3K1 | c.2590G>C p.E864Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.494); catalogued as COSV68121675, COSV68126736; called by muse, mutect2, varscan2
- MARCHF4 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV56107936; called by muse, mutect2, varscan2
- MED28 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV52847307; called by muse, mutect2
- MICU1 | c.1050G>C p.K350N (on ENST00000361114 / NM_001195518.2; = p.K356N on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV63147264; called by muse, mutect2, varscan2
- MMP15 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs765310950, COSV54681293; called by muse, mutect2
- MPEG1 | c.803C>G p.S268* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV57089641, COSV57090751; called by muse, mutect2, varscan2
- MTF1 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65990299; called by muse, mutect2
- NAP1L2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV65172982; called by muse, mutect2, varscan2
- NCK2 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51895591; called by muse, mutect2
- NDST4 | c.2234G>C p.G745A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52134240; called by muse, mutect2
- NEK11 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV53910142; called by muse, mutect2, varscan2
- NFE2L2 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV67962250; called by muse, mutect2
- NLRP4 | c.2369A>C p.H790P | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.087); catalogued as COSV100016305; called by muse, mutect2
- NOS2 | c.3162C>G p.V1054= | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58226865; called by muse, varscan2
- NSMAF | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1480252052, COSV50685753, COSV50698739; called by muse, mutect2, varscan2
- NUP133 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV54574655; called by muse, mutect2
- NUP210L | c.2836G>C p.E946Q | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.532); catalogued as COSV55155890; called by muse, mutect2, varscan2
- NXPH2 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55642053, COSV55646138; called by muse, mutect2, varscan2
- OPLAH | c.1073C>A p.S358Y | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101470750; called by muse, mutect2, varscan2
- OR13C2 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73377779; called by muse, mutect2, varscan2
- OR52E8 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV66204918, COSV66211458; called by muse, mutect2, varscan2
- PAPOLG | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53185208; called by muse, mutect2, varscan2
- PCDHB5 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV50649313; called by muse, mutect2, varscan2
- PHAX | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99881437; called by muse, mutect2
- PI4KB | c.437C>T p.S146L (on ENST00000368873 / NM_001369623.1; = p.S158L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV55020766; called by muse, mutect2
- PIGB | c.242G>C p.S81T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.424); catalogued as COSV51243728; called by muse, mutect2, varscan2
- PIGU | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54165723, COSV54166739; called by muse, mutect2, varscan2
- PIKFYVE | c.3431A>G p.D1144G | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs368966596; called by muse, mutect2, varscan2
- PLCB1 | c.3289G>C p.E1097Q | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62046443, COSV62064924; called by muse, mutect2, varscan2
- PLEKHB1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57050320; called by muse, mutect2, varscan2
- PLEKHG4 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV64613887; called by muse, mutect2, varscan2
- PLEKHG4 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs140708063; called by muse, mutect2, varscan2
- PLK4 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54639015, COSV54639816; called by muse, mutect2, varscan2
- PNCK | c.482C>G p.S161C (on ENST00000340888 / NM_001366975.1; = p.S244C on NM_001039582.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61745309; called by muse, mutect2, varscan2
- POLR3C | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as rs201403543, COSV61937349; called by muse, mutect2, varscan2
- POLR3C | c.1091G>C p.R364T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs782057644, COSV61937344; called by muse, mutect2, varscan2
- PRKCI | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55522128; called by muse, varscan2
- PRKCZ | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV101057743; called by muse, mutect2, varscan2
- PROX1 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.994); catalogued as rs972675744, COSV54776555, COSV99800240; called by muse, mutect2, varscan2
- PRPF38B | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64224479; called by muse, mutect2, varscan2
- PRSS48 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV71613599; called by muse, mutect2, varscan2
- PTPRG | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.962); catalogued as rs1484860890, COSV55659535; called by muse, mutect2
- RASAL2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs1312877885, COSV100862619; called by muse, mutect2
- RBBP5 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV52706459; called by muse, mutect2, varscan2
- RBM47 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 17/151 reads (11%) | catalogued as COSV55937358, COSV99920781; called by muse, mutect2, varscan2
- RCSD1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751462486, COSV63260718; called by muse, mutect2, varscan2
- RELL2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV51837074; called by muse, mutect2, varscan2
- RGS9 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV52228708; called by muse, mutect2, varscan2
- RIMS2 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV68113298; called by muse, mutect2, varscan2
- RNF220 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV62408992; called by muse, mutect2, varscan2
- SACS | c.8693G>A p.R2898H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs201977288, COSV66538818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELPLG | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs756234416; called by muse, mutect2
- SLC12A3 | c.2983G>C p.E995Q (on ENST00000563236 / NM_001126108.2; = p.E1004Q on NM_000339.3) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52638387; called by muse, varscan2
- SLC27A5 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189055667, COSV54021591, COSV99564406; ClinVar: uncertain significance; called by muse, varscan2
- SLC38A9 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs199794672, COSV59425692; called by muse, mutect2, varscan2
- SLFN13 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.305); catalogued as COSV53195271; called by muse, mutect2, varscan2
- SLMAP | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV55852297; called by muse, mutect2, varscan2
- SPTLC3 | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV65465203; called by muse, mutect2, varscan2
- SRI | c.250-1G>T p.X84_splice | Splice Site (SNP) | VAF 13/116 reads (11%) | catalogued as COSV56001477; called by muse, mutect2, varscan2
- STAG1 | c.1204C>A p.H402N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52621749; called by muse, varscan2
- STAG2 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV54354732, COSV54371270, COSV54374249; called by muse, mutect2, varscan2
- SV2C | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59217818; called by muse, mutect2, varscan2
- SVIL | c.1680G>T p.L560F | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63447332; called by muse, mutect2, varscan2
- SYTL1 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1314022146, COSV58874074; called by muse, mutect2
- TAS2R3 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV56092682; called by muse, mutect2, varscan2
- TCTE3 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1469723992, COSV100825399, COSV100825409; called by muse, mutect2
- TDRD6 | c.4074G>C p.M1358I | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60175586; called by muse, mutect2, varscan2
- TMEM74 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV52464473; called by muse, mutect2, varscan2
- TRANK1 | c.7588G>C p.E2530Q | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV57161935; called by muse, mutect2, varscan2
- TRAPPC12 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60851029; called by muse, mutect2, varscan2
- TRIM63 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65328365; called by muse, mutect2
- TSHZ3 | c.3218T>C p.L1073P | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV53680558; called by muse, mutect2, varscan2
- TTN | c.87853G>C p.D29285H (on ENST00000591111; = p.D21861H on NM_003319.4) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | PolyPhen probably damaging (0.988); catalogued as COSV60290511; called by muse, mutect2, varscan2
- TTN | c.46849G>C p.E15617Q (on ENST00000591111; = p.E8193Q on NM_003319.4) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | PolyPhen benign (0.018); catalogued as COSV60290541; called by muse, mutect2, varscan2
- TTYH2 | c.1260-1G>C p.X420_splice | Splice Site (SNP) | VAF 33/200 reads (17%) | catalogued as COSV53912917; called by muse, mutect2, varscan2
- TXNDC16 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.416); catalogued as rs947191574, COSV99909212, COSV99909410; called by muse, varscan2
- USF3 | c.5297C>T p.S1766L | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV57076590; called by muse, mutect2, varscan2
- USF3 | c.5006C>T p.S1669F | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57076601; called by muse, mutect2, varscan2
- VPS13C | c.5926C>T p.L1976F (on ENST00000644861 / NM_020821.3; = p.L1933F on NM_017684.5) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs896264117, COSV51428884; called by muse, mutect2
- VPS28 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52873325; called by muse, mutect2
- WDR3 | c.1616C>G p.S539C | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs776121352, COSV60466584; called by muse, mutect2, varscan2
- WRAP53 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53502630; called by muse, mutect2, varscan2
- XPOT | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV60347619; called by muse, mutect2
- ZFHX3 | c.6567C>G p.I2189M | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51732365; called by muse, mutect2
- ZFHX3 | c.5114C>T p.S1705L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV51732379, COSV51742716; called by muse, mutect2, varscan2
- ZFPM2 | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65873518, COSV65873577, COSV65875488; called by muse, mutect2
- ZGRF1 | c.6151C>T p.R2051* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV71393455; called by muse, mutect2, varscan2
- ZNF229 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.783); catalogued as rs1187421707, COSV52163975, COSV52164382; called by muse, mutect2, varscan2
- ZNF330 | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV53708292; called by muse, mutect2, varscan2
- ZNF347 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV61970578; called by muse, mutect2, varscan2
- ZNF483 | c.1880G>C p.R627T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58516050, COSV58517008; called by muse, mutect2, varscan2
- ZNF507 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.156); catalogued as rs769271924, COSV61333037; called by muse, mutect2, varscan2
- ZNF793 | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.175); catalogued as rs780425827, COSV71325161; called by muse, mutect2, varscan2
- PDXP | c.572dup p.G192Wfs*47 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- PSG6 | c.591del p.N198Tfs*25 | Frame Shift Del (DEL) | VAF 77/513 reads (15%) | called by mutect2, pindel, varscan2
- TBC1D4 | c.2690del p.L897Cfs*2 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.3144C>T p.L1048= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV55000725, COSV55006291; called by muse, mutect2, varscan2
- ALMS1 | c.7920C>T p.F2640= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as COSV52519930; called by muse, mutect2, varscan2
- ALMS1 | c.10323G>A p.K3441= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV52519941; called by muse, mutect2, varscan2
- ALPI | c.1053C>G p.V351= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV55015915; called by muse, mutect2, varscan2
- AMER3 | c.528G>A p.S176= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs776935592, COSV58467357, COSV58469465; called by muse, mutect2, varscan2
- ASIC2 | c.141G>A p.V47= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV63325784; called by muse, mutect2, varscan2
- C3orf56 | c.171C>G p.L57= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101228967, COSV67756468; called by muse, mutect2, varscan2
- CABP7 | c.459C>T p.I153= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV53364087; called by muse, mutect2
- CDH17 | c.1179C>G p.L393= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV50338191; called by muse, mutect2, varscan2
- CIAPIN1 | c.327G>A p.V109= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV67953594; called by muse, mutect2, varscan2
- CNGA3 | c.939C>T p.I313= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs138545096; called by muse, mutect2, varscan2
- COL24A1 | c.4155G>C p.L1385= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV65312545; called by muse, mutect2
- COL6A3 | c.9186G>A p.L3062= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99798262; called by mutect2, varscan2
- DNAH8 | c.438G>C p.L146= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as COSV59474889; called by muse, mutect2, varscan2
- DNAH8 | c.12828G>C p.L4276= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV59474917; called by muse, mutect2, varscan2
- DOP1B | c.5907G>A p.R1969= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV67695622; called by muse, mutect2, varscan2
- GCNT2 | c.339C>T p.L113= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV65457063; called by muse, mutect2
- ITGAX | c.3129G>A p.L1043= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV51650519; called by muse, mutect2, varscan2
- KCTD4 | c.612T>C p.N204= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV61242349; called by muse, mutect2, varscan2
- KIAA1549 | c.3396C>G p.L1132= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV54325581; called by muse, mutect2, varscan2
- KIF1B | c.4093C>T p.L1365= (on ENST00000377086 / NM_001365952.1; = p.L1319= on NM_015074.3) | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV55814844; called by muse, mutect2, varscan2
- LINGO3 | c.294C>T p.F98= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs780465898, COSV101347246; called by muse, mutect2
- LRFN3 | c.648G>A p.L216= | Silent (SNP) | VAF 62/406 reads (15%) | catalogued as COSV55818894; called by muse, mutect2, varscan2
- LRRC37A3 | c.1143G>A p.E381= | Silent (SNP) | VAF 28/602 reads (5%) | catalogued as COSV100141032; called by muse, mutect2
- MYL7 | c.123C>T p.F41= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV56268859; called by muse, mutect2
- MYO7A | c.924C>T p.L308= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV101289132; called by muse, mutect2
- MYO7B | c.534C>A p.I178= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV101268176, COSV67348096; called by muse, mutect2
- NEU3 | c.1116G>A p.Q372= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV53638750; called by muse, mutect2, varscan2
- NOP2 | c.1893G>A p.K631= (on ENST00000322166 / NM_001258308.2; = p.K627= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV59113129; called by muse, mutect2, varscan2
- NOS3 | c.3611G>A p.*1204= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99871634; called by muse, mutect2, varscan2
- NYNRIN | c.5400C>A p.L1800= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as COSV66844567; called by muse, mutect2
- OR2M3 | c.834C>T p.Y278= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as rs1236753525, COSV71759245; called by muse, mutect2, varscan2
- OR2M5 | c.219C>T p.L73= | Silent (SNP) | VAF 56/505 reads (11%) | catalogued as rs1188773937, COSV63546909; called by muse, mutect2, varscan2
- OR4C46 | c.213T>C p.Y71= | Silent (SNP) | VAF 67/267 reads (25%) | catalogued as rs370219354; called by muse, mutect2, varscan2
- OVOL1 | c.565C>T p.L189= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV60120483; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.447C>T p.L149= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV57968118; called by muse, mutect2, varscan2
- POLR3A | c.2520C>T p.S840= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs892342504, COSV64931924; called by muse, mutect2, varscan2
- PTPRC | c.1140C>T p.N380= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as rs200643724; ClinVar: likely benign; called by muse, mutect2
- RSL1D1 | c.1410G>C p.V470= | Silent (SNP) | VAF 51/330 reads (15%) | catalogued as COSV63078383; called by muse, mutect2, varscan2
- SALL3 | c.1662G>A p.Q554= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV73306439; called by muse, mutect2, varscan2
- SCN11A | c.3306C>T p.I1102= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV56570765; called by muse, mutect2, varscan2
- SCN2A | c.4995C>G p.L1665= | Silent (SNP) | VAF 19/201 reads (9%) | catalogued as COSV51853233; called by muse, mutect2
- SLC25A28 | c.1005G>A p.Q335= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV65125642; called by muse, mutect2, varscan2
- SYK | c.309C>T p.L103= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV65329807; called by muse, mutect2, varscan2
- TRIM71 | c.987G>A p.L329= | Silent (SNP) | VAF 31/195 reads (16%) | catalogued as rs1220511377, COSV67472455; called by muse, mutect2, varscan2
- TTN | c.41307C>T p.F13769= (on ENST00000591111; = p.F6345= on NM_003319.4) | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV60290573; called by muse, mutect2, varscan2
- USP24 | c.1440G>A p.K480= | Silent (SNP) | VAF 16/159 reads (10%) | catalogued as COSV53776615; called by muse, mutect2, varscan2
- VIM | c.1269G>C p.L423= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV56407413, COSV56408210; called by muse, mutect2, varscan2
- XPNPEP1 | c.1473C>T p.L491= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV59170751; called by muse, mutect2
- ZNF124 | c.963G>A p.Q321= (on ENST00000543802 / NM_001297568.1; = p.Q259= on NM_003431.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV61507356, COSV61507864; called by muse, mutect2
- ZNF142 | c.3957G>C p.L1319= (on ENST00000411696 / NM_001379660.1; = p.L1119= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV68745245; called by muse, mutect2
- ZNF436 | c.18C>T p.L6= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1239105441, COSV58358697; called by muse, mutect2, varscan2
- AFDN | chr6:167825721 G>A | 5'Flank (SNP) | VAF 11/101 reads (11%) | catalogued as rs764117945; called by muse, mutect2, varscan2
- CFAP61 | c.2503+2288G>A | Intron (SNP) | VAF 24/406 reads (6%) | catalogued as COSV55643851; called by muse, mutect2
- GP6 | c.*495C>G | 3'UTR (SNP) | VAF 18/137 reads (13%) | catalogued as COSV59979229; called by muse, mutect2, varscan2
- SNORD114-28 | n.30G>C | RNA (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- ZNF322P1 | n.286G>C | RNA (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
